Gene-level copy-number profile of tumor specimen TCGA-FS-A4F4-06A from TCGA case TCGA-FS-A4F4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.7 years (25,467 days).
Specimen TCGA-FS-A4F4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a897a12a-9697-40d6-84d4-6e397e49a0a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A4F4-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b98a0ea-f633-4988-a098-06e9045f820a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 117; copy number 2: 11,704; copy number 3: 6,209; copy number 4: 36,751; copy number 5: 637; copy number 6: 1,537; copy number 7: 1,921; copy number 8: 262; copy number 9: 211; copy number 10: 28; copy number 11: 45; copy number 12: 39; copy number 13: 1; copy number 14: 8; copy number 15: 49; copy number 16: 22; copy number 17: 10; copy number 18: 12; copy number 20: 25; copy number 21: 5; copy number 22: 6; copy number 23: 8; copy number 24: 69; copy number 25: 6; copy number 27: 1; copy number 28: 99; copy number 29: 2; copy number 32: 1; copy number 36: 12; copy number 44: 3; copy number 54: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A4F4-06A-12D-A25P-01): tumor purity 0.79, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 666 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:850,291–1,112,063, 10 genes, copy number 28 (within-gene range 2–28): BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635.
- chr5:1,225,381–1,380,107, 8 genes, copy number 14 (within-gene range 2–14): SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32.
- chr5:4,012,708–4,440,259, 4 genes, copy number 27–44: AC025773.1, AC025187.1, LINC02063, AC106799.3.
- chr5:4,512,262–4,516,776, 1 gene, copy number 23: AC106799.1.
- chr5:5,375,723–5,376,836, 1 gene, copy number 23: ALG3P1.
- chr5:6,019,029–6,137,171, 3 genes, copy number 16: AC010266.2, AC010266.1, AC026797.1.
- chr5:6,378,674–6,533,200, 3 genes, copy number 21 (within-gene range 2–21): AC093307.1, UBE2QL1, AC027334.1.
- chr5:6,765,891–7,830,081, 21 genes, copy number 9–25 (within-gene range 2–33): LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1.
- chr5:8,614,356–8,794,197, 10 genes, copy number 12: AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3.
- chr5:14,356,886–14,359,285, 1 gene, copy number 23: AC016549.1.
- chr5:14,651,941–14,961,393, 11 genes, copy number 18–20: EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1.
- chr5:16,661,907–16,936,288, 1 gene, copy number 32 (within-gene range 2–32): MYO10.
- chr5:17,202,274–17,955,857, 41 genes, copy number 9–22: DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223.
- chr5:21,196,720–21,196,860, 1 gene, copy number 23: AC140172.1.
- chr5:29,948,828–30,248,893, 3 genes, copy number 21–25: RN7SKP207, AC018765.1, HPRT1P2.
- chr5:33,987,174–34,124,528, 1 gene, copy number 24 (within-gene range 8–24): C1QTNF3-AMACR.
- chr5:34,017,858–34,158,767, 4 genes, copy number 24 (within-gene range 8–24): C1QTNF3, AC139792.2, AC139792.3, AC139792.1.
- chr5:34,651,457–35,879,603, 18 genes, copy number 18–54 (within-gene range 6–54): AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2, PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R.
- chr5:37,619,985–37,620,088, 1 gene, copy number 11: RNU6-1190P.
- chr5:40,512,333–40,755,963, 2 genes, copy number 9 (within-gene range 4–9): TTC33, SNORA63.
- chr7:106,208,167–111,562,517, 62 genes, copy number 9–12 (broad region; genes not listed).
- chr7:113,486,407–122,310,691, 108 genes, copy number 9–16 (broad region; genes not listed).
- chr7:122,328,469–122,440,388, 1 gene, copy number 9: AC004594.1.
- chr16:11,547,722–11,916,082, 13 genes, copy number 11 (within-gene range 7–11): LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1.
- chr22:17,628,855–17,730,855, 1 gene, copy number 13 (within-gene range 2–13): BCL2L13.
- chr22:20,058,030–20,354,387, 24 genes, copy number 10: AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5.
- chr22:20,707,691–21,517,533, 50 genes, copy number 24 (within-gene range 7–24): PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, FAM246A, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2, Metazoa_SRP, TMEM191C, PI4KAP2.
- chr22:24,901,147–26,031,045, 34 genes, copy number 9 (within-gene range 2–9): AL049759.1, TMEM211, KIAA1671, AL022323.2, AL022323.4, AL022323.1, AL022323.3, KIAA1671-AS1, Z99916.2, CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1.
- chr22:26,161,834–26,645,336, 18 genes, copy number 11–24: LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1.
- chr22:27,851,669–27,920,134, 1 gene, copy number 11 (within-gene range 4–11): PITPNB.
- chr22:27,919,384–27,922,178, 4 genes, copy number 11: AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.
- chr22:38,200,767–38,398,522, 7 genes, copy number 17 (within-gene range 7–17): MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E.
- chr22:40,769,630–45,341,955, 156 genes, copy number 12–28 (broad region; genes not listed).
- chr22:45,604,432–45,891,438, 8 genes, copy number 20: LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1.
- chr22:46,150,521–46,243,756, 2 genes, copy number 29: PPARA, FP325332.1.
- chr22:46,330,875–46,762,563, 7 genes, copy number 11–23: TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1.
- chr22:46,914,092–46,916,042, 1 gene, copy number 23: TBC1D22A-AS1.
- chr22:47,345,569–49,266,080, 24 genes, copy number 9–16: Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2, TAFA5, Z84468.1, MIR4535, LINC01310, AL078622.1, Z82202.2, RPL35P8, Z82202.1.

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
